Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3844, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3844-01A (Primary Tumor).

Findings and diagnosis relating to the problem:

The material in I) - as regards block A - shows a marked finding in terms of an adenocarcinoma of the colon with characteristic tumor cell groups, mostly in a tubular arrangement, and a marked tendency to spread to the fatty connective tissue, as well as moderate to low-grade lymph nodes (G2 to 3, pT3, L1, V1)

The material also shows seven conglomerate metastases of the carcinoma described with extensive necrosis (7 of 18) and – with regard to the resection margins – free resection margins, here of the cryptic epithelium type with goblet cells, regular submucosa and muscularis

and in II a regular anastomosis ring, here with regular cryptic epithelium, lined with goblet cells, isolated lymph follicles and regular submucosa and muscularis.

Tumor classification:

ICDO-DA M-8140/3, G2 to 3, pT3, L1, V1, pN2, locally R0.

Source: NCI Genomic Data Commons file e9db252f-284b-406e-86dd-d987ab110b2b (TCGA-AA-3844.8445E6A1-3A39-4261-B971-D3409F6B88A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).